Somatic mutation profile of tumor specimen MMRF_1518_2_BM_CD138pos (aliquot MMRF_1518_2_BM_CD138pos_T2_KHS5U_K14081) from MMRF case MMRF_1518, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.5 years (23,200 days).
Specimen MMRF_1518_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cb8ddd7-303c-4581-88f1-c616afaf4b1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1518_3_PB_Whole (Blood Derived Normal), aliquot MMRF_1518_3_PB_Whole_C3_KBS5U_L05573; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/434b57c0-aa69-45ec-9e0e-8c3c3951ac3e

The open-access MAF lists 165 somatic variants for this specimen: 54 protein-altering or splice-affecting, 25 silent, 86 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, 3'UTR 40, Silent 25, Intron 21, 5'Flank 11, 3'Flank 6, Nonsense Mutation 5, 5'UTR 4, RNA 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM22 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.843); catalogued as COSV99717630; called by muse, mutect2, varscan2
- DLX2 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 73/127 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs1457752592; called by muse, mutect2, varscan2
- EPHB1 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 84/121 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV67654980, COSV67659512, COSV67664485; called by muse, mutect2, varscan2
- GRIN2D | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV54380226; called by muse, mutect2, varscan2
- IGHV2-70 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs184904469; called by muse, varscan2
- KCNT1 | c.2039C>T p.T680M (on ENST00000488444; = p.T699M on NM_020822.3) | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.238); catalogued as rs538197009, COSV53700849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- L3MBTL3 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 40/134 reads (30%) | catalogued as COSV62384340; called by muse, mutect2, varscan2
- MIS18BP1 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs144218247; called by muse, mutect2, varscan2
- NFXL1 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 46/82 reads (56%) | catalogued as COSV61200196; called by muse, mutect2, varscan2
- NFYC | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV58125969; called by muse, mutect2, varscan2
- PLEKHG4B | c.658C>T p.R220C (on ENST00000283426; = p.R576C on NM_052909.5) | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149661863, COSV52052280; called by muse, mutect2
- PPFIA3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61951924, COSV61955098; called by muse, mutect2, varscan2
- PTPRQ | c.3399C>G p.I1133M (on ENST00000616559; = p.I1091M on NM_001145026.2) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.183); catalogued as rs1343207437; called by muse, mutect2, varscan2
- RANBP3L | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs751770258, COSV56954604; called by muse, mutect2
- SELP | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as rs1557963517; called by mutect2, varscan2
- SETD1B | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.013); catalogued as rs1235576836; called by muse, mutect2, varscan2
- THAP7 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs755408769, COSV53145783, COSV99301459; called by muse, mutect2, varscan2
- USH2A | c.84A>G p.I28M | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.177); catalogued as rs1270426964; called by muse, mutect2
- VWDE | c.656dup p.N219Kfs*11 | Frame Shift Ins (INS) | VAF 21/182 reads (12%) | catalogued as rs907015274; called by mutect2, varscan2
- ACBD5 | c.196G>A p.E66K (on ENST00000375888 / NM_001352568.1; = p.E68K on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/169 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- AFAP1L2 | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 91/144 reads (63%) | called by muse, varscan2
- ATXN10 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CYB5D2 | c.653T>A p.V218E | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- DOCK7 | c.3595G>T p.D1199Y (on ENST00000635253 / NM_001367561.1; = p.D1168Y on NM_033407.3) | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- DPYSL4 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- DYNC1I2 | c.570G>C p.E190D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- GRHPR | c.699G>C p.K233N | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GRPEL2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HMGCS2 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- IGLV2-23 | c.313G>C p.A105P | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KLHL4 | c.1650G>T p.W550C | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LHFPL2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- MEX3C | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NMUR2 | c.845C>A p.A282D | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- OR1N1 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PKHD1L1 | c.11283C>A p.C3761* | Nonsense Mutation (SNP) | VAF 71/132 reads (54%) | called by muse, mutect2, varscan2
- PPIL6 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PTPN22 | c.2114T>G p.F705C (on ENST00000359785 / NM_001193431.2; = p.F650C on NM_012411.5) | Missense Mutation (SNP) | VAF 55/82 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RGS22 | c.3758T>C p.L1253S | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF138 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by mutect2, varscan2
- RPL21 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SF3B1 | c.959G>C p.G320A | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A27 | c.234C>G p.I78M | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SLC4A7 | c.1214A>G p.E405G | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2
- SNX1 | c.589C>G p.L197V | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- SYNJ1 | c.3224C>T p.S1075F | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- TNFRSF10B | c.493G>T p.V165F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by mutect2, varscan2
- TRAPPC5 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- UBR7 | c.953A>C p.D318A | Missense Mutation (SNP) | VAF 47/50 reads (94%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by mutect2, varscan2
- VPS53 | c.1891G>A p.V631I (on ENST00000571805 / NM_001366253.2; = p.V602I on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- WDR83 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- WDR90 | c.2602G>T p.E868* | Nonsense Mutation (SNP) | VAF 52/53 reads (98%) | called by muse, mutect2, varscan2
- ZBTB33 | c.842T>C p.I281T | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); called by muse, mutect2
- ZNF407 | c.5135A>T p.K1712I | Missense Mutation (SNP) | VAF 76/147 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCA13 | c.2769C>T p.I923= | Silent (SNP) | VAF 81/138 reads (59%) | called by muse, mutect2, varscan2
- ADAM23 | c.2214C>T p.L738= | Silent (SNP) | VAF 57/94 reads (61%) | catalogued as rs748943848, COSV52216648; called by muse, mutect2, varscan2
- BTBD11 | c.1230G>A p.L410= | Silent (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- CACNG1 | c.144G>A p.A48= | Silent (SNP) | VAF 121/369 reads (33%) | catalogued as rs144676810; called by muse, mutect2, varscan2
- CERS5 | c.129C>T p.R43= | Silent (SNP) | VAF 40/101 reads (40%) | called by muse, mutect2, varscan2
- CSMD3 | c.8163A>T p.V2721= | Silent (SNP) | VAF 54/177 reads (31%) | called by muse, mutect2, varscan2
- DENND1A | c.735C>T p.Y245= | Silent (SNP) | VAF 55/128 reads (43%) | called by muse, mutect2, varscan2
- DOCK10 | c.4857C>T p.A1619= | Silent (SNP) | VAF 45/163 reads (28%) | catalogued as rs1219456600, COSV51379124; called by muse, mutect2, varscan2
- HCN3 | c.138G>A p.R46= | Silent (SNP) | VAF 42/44 reads (95%) | catalogued as COSV100751883; called by muse, mutect2, varscan2
- HIP1 | c.1215G>A p.L405= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs781989600; called by muse, mutect2, varscan2
- IRGQ | c.1560G>A p.L520= | Silent (SNP) | VAF 38/70 reads (54%) | catalogued as rs764545585; called by muse, mutect2, varscan2
- JKAMP | c.354C>T p.I118= (on ENST00000554271 / NM_001284201.1; = p.I104= on NM_016475.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2, varscan2
- KCTD1 | c.717G>A p.L239= | Silent (SNP) | VAF 79/170 reads (46%) | catalogued as rs764837166; called by muse, mutect2, varscan2
- LMX1B | c.375C>T p.T125= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs921576454; ClinVar: uncertain significance; called by muse, mutect2
- MAFA | c.309C>T p.A103= | Silent (SNP) | VAF 23/29 reads (79%) | called by muse, mutect2, varscan2
- MEAK7 | c.888C>T p.L296= | Silent (SNP) | VAF 55/55 reads (100%) | catalogued as rs143458469; called by muse, mutect2, varscan2
- PAFAH1B3 | c.87G>A p.R29= | Silent (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- PLEKHA8 | c.1209A>G p.E403= | Silent (SNP) | VAF 10/58 reads (17%) | called by mutect2, varscan2
- PPIL6 | c.540A>T p.G180= | Silent (SNP) | VAF 56/227 reads (25%) | called by muse, varscan2
- SCYL2 | c.2352C>T p.F784= | Silent (SNP) | VAF 33/56 reads (59%) | catalogued as rs745664030; called by muse, mutect2, varscan2
- SELE | c.1077C>T p.I359= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV60974854; called by muse, mutect2, varscan2
- SP8 | c.1311G>A p.T437= (on ENST00000361443 / NM_198956.4; = p.T455= on NM_182700.6) | Silent (SNP) | VAF 19/25 reads (76%) | catalogued as rs1297485590; called by muse, mutect2, varscan2
- STXBP2 | c.18G>A p.L6= | Silent (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- TGS1 | c.69G>A p.K23= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs761903979; called by muse, mutect2, varscan2
- TMEM219 | c.333G>C p.L111= | Silent (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- A1CF | chr10:50806506 C>T | 3'Flank (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- AAK1 | c.*10180G>A | 3'UTR (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- AANAT | chr17:76465965 T>C | 5'Flank (SNP) | VAF 6/9 reads (67%) | called by muse, varscan2
- ABCC1 | c.*590G>C | 3'UTR (SNP) | VAF 31/48 reads (65%) | called by muse, mutect2, varscan2
- AC016596.1 | chr5:56002104 G>T | 5'Flank (SNP) | VAF 53/77 reads (69%) | called by muse, mutect2, varscan2
- AC027612.1 | n.1856G>A | RNA (SNP) | VAF 10/76 reads (13%) | catalogued as rs982832244; called by muse, mutect2, varscan2
- ACTL6B | c.102+52A>C | Intron (SNP) | VAF 63/121 reads (52%) | called by muse, mutect2, varscan2
- ADH6 | chr4:99204561 C>A | 3'Flank (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- ANKRD13C | c.1215+49A>T | Intron (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- ANKRD13D | c.*1530G>A | 3'UTR (SNP) | VAF 88/121 reads (73%) | catalogued as COSV57386361; called by muse, mutect2, varscan2
- ANKRD52 | c.*4129A>T | 3'UTR (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- ARL15 | c.*189C>T | 3'UTR (SNP) | VAF 46/78 reads (59%) | called by muse, mutect2, varscan2
- ARMC8 | c.1135-1413G>C | Intron (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- BIRC8 | n.993G>C | RNA (SNP) | VAF 29/65 reads (45%) | catalogued as COSV101461363, COSV70346632; called by muse, mutect2, varscan2
- BRK1 | c.-12C>T | 5'UTR (SNP) | VAF 39/60 reads (65%) | catalogued as COSV99845147; called by muse, mutect2, varscan2
- CALHM1 | c.-25G>T | 5'UTR (SNP) | VAF 64/130 reads (49%) | called by muse, mutect2, varscan2
- CAMK4 | c.*5806G>C | 3'UTR (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- CCAR2 | c.2728-140G>A | Intron (SNP) | VAF 87/127 reads (69%) | called by mutect2, varscan2
- CCDC57 | c.*83G>T | 3'UTR (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- CELF2 | c.*3210G>C | 3'UTR (SNP) | VAF 29/66 reads (44%) | catalogued as rs1050946; called by muse, mutect2, varscan2
- CHM | c.*3357T>G | 3'UTR (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- CHRND | chr2:232526051 C>A | 5'Flank (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- CYGB | chr17:76538232 C>A | 5'Flank (SNP) | VAF 31/51 reads (61%) | called by muse, mutect2, varscan2
- DNAI4 | c.*53C>G | 3'UTR (SNP) | VAF 85/156 reads (54%) | called by muse, varscan2
- DNAJC10 | c.*2493G>C | 3'UTR (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- DOCK2 | c.5166+17G>A | Intron (SNP) | VAF 7/8 reads (88%) | called by muse, mutect2, varscan2
- EEA1 | c.*884G>C | 3'UTR (SNP) | VAF 35/120 reads (29%) | catalogued as rs538576413; called by muse, mutect2, varscan2
- EXTL3 | c.*489C>T | 3'UTR (SNP) | VAF 16/58 reads (28%) | called by muse, mutect2, varscan2
- F2RL1 | c.*1267G>T | 3'UTR (SNP) | VAF 50/87 reads (57%) | called by muse, mutect2, varscan2
- FAM83H | c.*708del | 3'UTR (DEL) | VAF 14/20 reads (70%) | catalogued as rs1352640844; called by mutect2, varscan2
- FBXO9 | c.*211dup | 3'UTR (INS) | VAF 30/64 reads (47%) | catalogued as rs921789811; called by mutect2, varscan2
- GOSR2 | chr17:46940741 C>T | 3'Flank (SNP) | VAF 17/36 reads (47%) | catalogued as rs1432881074; called by muse, mutect2, varscan2
- IFNAR1 | c.*2689C>T | 3'UTR (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- INTS10 | c.197+85G>A | Intron (SNP) | VAF 9/41 reads (22%) | catalogued as rs1033914342; called by muse, mutect2, varscan2
- IPO9 | c.*1554G>C | 3'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- KRT78 | c.*1182C>T | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- MALRD1 | c.5030-2482C>A | Intron (SNP) | VAF 45/262 reads (17%) | called by muse, mutect2, varscan2
- MAP4 | c.292+4167C>G | Intron (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- MFSD14A | c.*1012A>C | 3'UTR (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2
- MRPL37 | c.*29C>T | 3'UTR (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- MTO1 | chr6:73461648 T>C | 5'Flank (SNP) | VAF 14/37 reads (38%) | called by mutect2, varscan2
- NASP | c.-18C>T | 5'UTR (SNP) | VAF 106/201 reads (53%) | catalogued as COSV63113706; called by muse, mutect2, varscan2
- NDUFA5 | c.*4689_*4691del | 3'UTR (DEL) | VAF 26/72 reads (36%) | called by mutect2, pindel, varscan2
- NHEJ1 | c.*868C>G | 3'UTR (SNP) | VAF 6/16 reads (38%) | catalogued as rs575933532; called by muse, mutect2, varscan2
- OR10D1P | n.333C>T | RNA (SNP) | VAF 44/86 reads (51%) | called by muse, mutect2, varscan2
- PARP9 | c.2185+347T>A | Intron (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- PARP9 | c.2185+346T>A | Intron (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- PCDH7 | c.*226G>A | 3'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- PDZD4 | c.296+324G>A | Intron (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- PEX11A | chr15:89690762 G>A | 5'Flank (SNP) | VAF 41/86 reads (48%) | catalogued as COSV51534079; called by muse, mutect2, varscan2
- PGK1 | c.*780C>A | 3'UTR (SNP) | VAF 37/93 reads (40%) | called by muse, varscan2
- PGK1 | c.*781C>T | 3'UTR (SNP) | VAF 36/92 reads (39%) | called by muse, varscan2
- PGR | c.2646+43G>C | Intron (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- PHACTR4 | chr1:28369669 C>T | 5'Flank (SNP) | VAF 10/15 reads (67%) | called by muse, mutect2, varscan2
- PHC1 | c.-57-39A>G | Intron (SNP) | VAF 112/219 reads (51%) | called by muse, mutect2, varscan2
- PIN4 | c.313-66C>T | Intron (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- PPARGC1A | c.234+1381C>T | Intron (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- PPM1A | c.952+1666G>C | Intron (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2, varscan2
- PPM1F | c.355+1416A>G | Intron (SNP) | VAF 41/78 reads (53%) | called by muse, mutect2, varscan2
- RBM7 | c.*1325C>T | 3'UTR (SNP) | VAF 33/75 reads (44%) | catalogued as rs1431228334; called by muse, mutect2, varscan2
- ROBO2 | c.3554+183G>T | Intron (SNP) | VAF 58/92 reads (63%) | called by muse, mutect2, varscan2
- SH2D1B | c.*1394dup | 3'UTR (INS) | VAF 44/126 reads (35%) | called by mutect2, varscan2
- SLC47A1 | c.*1365C>G | 3'UTR (SNP) | VAF 40/51 reads (78%) | called by muse, mutect2, varscan2
- SND1 | c.-147G>A | 5'UTR (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- SP110 | c.1590+128C>T | Intron (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2, varscan2
- STK40 | c.1089+355T>C | Intron (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- STX6 | c.*3752C>T | 3'UTR (SNP) | VAF 24/69 reads (35%) | catalogued as rs763249474; called by muse, mutect2, varscan2
- SWAP70 | c.*1429G>T | 3'UTR (SNP) | VAF 50/71 reads (70%) | called by muse, mutect2, varscan2
- TAF7L | c.*787_*807del | 3'UTR (DEL) | VAF 28/71 reads (39%) | called by mutect2, pindel, varscan2
- TENT5D | c.*1252G>A | 3'UTR (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- TF | chr3:133746143 C>T | 5'Flank (SNP) | VAF 37/61 reads (61%) | called by muse, mutect2, varscan2
- TGFA | chr2:70553843 G>A | 5'Flank (SNP) | VAF 6/22 reads (27%) | catalogued as rs1309611379; called by muse, mutect2, varscan2
- TMEM108 | c.1451-2863T>C | Intron (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- TNRC6B | c.*5819C>G | 3'UTR (SNP) | VAF 31/65 reads (48%) | catalogued as rs1001289255; called by muse, mutect2, varscan2
- TPD52 | chr8:80035787 G>A | 3'Flank (SNP) | VAF 18/71 reads (25%) | called by muse, varscan2
- TPD52 | chr8:80035912 G>A | 3'Flank (SNP) | VAF 6/44 reads (14%) | called by muse, varscan2
- TPD52 | chr8:80036033 G>A | 3'Flank (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- TRAPPC6B | c.*2107T>A | 3'UTR (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- TULP4 | c.*4966G>C | 3'UTR (SNP) | VAF 37/60 reads (62%) | called by muse, mutect2, varscan2
- TXNL1 | chr18:56638600 C>T | 5'Flank (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- XKR4 | c.*1900G>T | 3'UTR (SNP) | VAF 35/54 reads (65%) | catalogued as COSV59316473; called by muse, mutect2, varscan2
- YBX1P1 | n.850C>T | RNA (SNP) | VAF 41/49 reads (84%) | called by muse, mutect2, varscan2
- ZFP37 | c.*2740C>T | 3'UTR (SNP) | VAF 16/47 reads (34%) | catalogued as rs765617290; called by muse, mutect2, varscan2
- ZNF252P | chr8:145005321 G>C | 5'Flank (SNP) | VAF 16/30 reads (53%) | catalogued as rs1201091102; called by muse, mutect2, varscan2
- ZNF813 | c.*639G>C | 3'UTR (SNP) | VAF 18/460 reads (4%) | called by muse, mutect2
- ZNF84 | c.*3725T>A | 3'UTR (SNP) | VAF 50/81 reads (62%) | called by muse, mutect2, varscan2
